Somatic mutation profile of tumor specimen TCGA-EY-A4KR-01A (aliquot TCGA-EY-A4KR-01A-11D-A27P-09) from TCGA case TCGA-EY-A4KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 56.6 years (20,669 days).
Specimen TCGA-EY-A4KR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a440176-818d-45d4-a828-ca669adf2eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A4KR-10A (Blood Derived Normal), aliquot TCGA-EY-A4KR-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71495091-a1ad-414a-83e6-c634a66d58c3

The open-access MAF lists 89 somatic variants for this specimen: 62 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, Frame Shift Del 4, Nonsense Mutation 2, 5'UTR 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP2 | c.2328G>T p.Q776H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100461989; called by muse, mutect2
- ADAMTS20 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101239206; called by muse, mutect2, varscan2
- ADGRE2 | c.2018C>A p.P673H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100215960; called by muse, mutect2
- AL121899.2 | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101198437; called by muse, mutect2
- ANKRD30A | c.1550C>A p.P517H (on ENST00000611781; = p.P461H on NM_052997.2) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100653416; called by muse, mutect2
- ARF1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV99683165; called by muse, mutect2, varscan2
- CD93 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs998960775, COSV99849180, COSV99849574; called by muse, mutect2, varscan2
- CDH2 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771423706, COSV99296685; called by muse, mutect2
- CLDN4 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs200176069, COSV52896949, COSV99936548; called by muse, mutect2
- COMMD6 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs1308674119, COSV100869867; called by muse, mutect2, varscan2
- CUL3 | c.1452G>C p.M484I | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs768583356, COSV100024208; called by muse, mutect2, varscan2
- FAM151A | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV100156878; called by muse, mutect2
- FAM98A | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs1262954038, COSV53210252, COSV99479106; called by muse, mutect2, varscan2
- FBXO10 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99446589; called by muse, mutect2, varscan2
- H2AW | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64209671; called by muse, mutect2
- HDAC7 | c.1310G>C p.R437T (on ENST00000427332; = p.R476T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99316073; called by muse, mutect2, varscan2
- HERC2 | c.7766G>T p.G2589V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV99873203; called by muse, mutect2, varscan2
- HTR3A | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs776787664, COSV100248403; called by muse, mutect2, varscan2
- ICAM5 | c.1737C>G p.S579R | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV55746365, COSV99703308; called by muse, mutect2
- IL22RA2 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs758405434, COSV99760657; called by muse, mutect2, varscan2
- ITGA7 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767498152, COSV99145450; called by muse, mutect2, varscan2
- KCNK17 | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs747419286, COSV64686394; called by muse, mutect2, varscan2
- KLHL4 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs1255180871, COSV100909502, COSV100910123; called by muse, mutect2, varscan2
- LTBP4 | c.4450G>A p.G1484S (on ENST00000308370 / NM_001042544.1; = p.G1447S on NM_003573.2) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99191151; called by muse, mutect2
- LUC7L3 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99536869; called by muse, mutect2, varscan2
- ME2 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV100360756; called by muse, varscan2
- MTPAP | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99554022; called by muse, mutect2, varscan2
- MYOCD | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs770965947, COSV100590667; called by muse, mutect2, varscan2
- MYOZ1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753227727, COSV100831848; called by muse, mutect2, varscan2
- NUP37 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV51837574, COSV99195846; called by muse, mutect2, varscan2
- PAQR8 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1475388362, COSV100658440; called by muse, mutect2
- PCDHA4 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1377582762, COSV63547054; called by muse, mutect2, varscan2
- PCDHA9 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1365314674, COSV100969448; called by muse, mutect2, varscan2
- PCDHB2 | c.414A>C p.K138N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV99523096; called by muse, mutect2, varscan2
- PDCD11 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs753738057, COSV100874311; called by muse, mutect2
- PEA15 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.992); catalogued as COSV100470381, COSV100470741; called by muse, mutect2
- PPFIA2 | c.3251T>C p.L1084S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100333076; called by muse, mutect2
- PPM1E | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100376176; called by muse, mutect2, varscan2
- PUM1 | c.3022C>G p.R1008G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99927929; called by muse, mutect2
- RPL6 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99176124; called by muse, mutect2, varscan2
- SDSL | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100615229; called by muse, mutect2, varscan2
- SIRT1 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99281762; called by muse, mutect2
- SLC2A9 | c.537C>T p.G179= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as rs753136929, COSV53330367, COSV53330844; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC9A6 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100857893; called by muse, mutect2, varscan2
- SRCIN1 | c.3134G>A p.R1045Q (on ENST00000621492; = p.R1011Q on NM_025248.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1312841523; called by muse, mutect2, varscan2
- TAF2 | c.3488A>G p.H1163R | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV100978650; called by muse, mutect2, varscan2
- TSPAN19 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs777078565, COSV101468087; called by muse, mutect2, varscan2
- TTN | c.54311C>A p.T18104N (on ENST00000591111; = p.T10680N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | PolyPhen possibly damaging (0.744); catalogued as COSV100610308; called by muse, mutect2, varscan2
- USP31 | c.2095G>C p.G699R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs764263014, COSV99565135; called by muse, mutect2, varscan2
- UTP25 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101504743; called by muse, mutect2, varscan2
- ZBTB1 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100704085; called by muse, mutect2, varscan2
- ZFP28 | c.2071C>A p.H691N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100019527; called by muse, mutect2
- ZNF135 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776610394, COSV100536591; called by muse, mutect2
- ZNF486 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs782614261, COSV58717909, COSV58722163; called by muse, mutect2, varscan2
- ZNF527 | c.1196C>G p.A399G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100648727; called by muse, mutect2, varscan2
- ZNF75A | c.452A>C p.H151P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV101556636; called by muse, mutect2
- EIF4A1 | c.514+2_514+3del | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- NAP1L3 | c.1348_1349del p.M450Dfs*14 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- SCN11A | c.2609C>A p.A870E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- SKIL | c.1842del p.K614Nfs*8 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- ALLC | c.939G>A p.P313= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs186926132; called by muse, mutect2, varscan2
- COG1 | c.2491C>A p.R831= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV100245289; called by muse, mutect2
- DSG1 | c.2514C>T p.T838= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs758293574, COSV99935835, COSV99935935; called by muse, mutect2
- ELAPOR1 | c.2898C>T p.G966= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs529832723, COSV64041139; called by muse, mutect2, varscan2
- FBXO33 | c.1293G>C p.V431= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99980870; called by muse, mutect2, varscan2
- LRP5 | c.2886C>T p.D962= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs144415767; called by muse, mutect2, varscan2
- LRRC34 | c.474C>G p.L158= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100336280, COSV57187167; called by muse, mutect2
- NKAIN3 | c.105G>A p.A35= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs372067746, COSV100136346; called by muse, mutect2, varscan2
- NOS2 | c.2638C>T p.L880= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs1185809043, COSV100569638; called by muse, mutect2
- NUDT8 | c.204C>T p.G68= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs376182284; called by muse, mutect2, varscan2
- OR6B2 | c.282C>T p.F94= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs750021015, COSV53153142; called by muse, mutect2, varscan2
- RCC2 | c.1449C>T p.G483= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100965140; called by muse, mutect2
- RSBN1 | c.447T>G p.P149= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99793179; called by muse, mutect2, varscan2
- SH3GL2 | c.1041G>A p.L347= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV101014293; called by muse, mutect2, varscan2
- SMURF2 | c.1374G>A p.Q458= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1555684144, COSV99300642; called by muse, mutect2
- SRRT | c.1284C>T p.I428= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs768008445, COSV53819097; called by muse, mutect2, varscan2
- STON2 | c.870C>T p.V290= (on ENST00000649389 / NM_001366849.2; = p.V233= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99964696; called by muse, mutect2
- TRAF3IP2 | c.903G>A p.P301= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs746125245, COSV60677222; called by muse, mutect2, varscan2
- USP22 | c.1074A>G p.G358= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99820237; called by muse, mutect2, varscan2
- VPS33A | c.279C>T p.I93= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs778682921, COSV99931337; called by muse, mutect2, varscan2
- WT1 | c.1086A>G p.V362= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100187994; called by muse, mutect2, varscan2
- ZNF423 | c.1845G>A p.S615= (on ENST00000563137 / NM_001379286.1; = p.S607= on NM_015069.4) | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs61755181, COSV99281863; called by muse, varscan2
- ZNF674 | c.168G>C p.V56= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV101345036; called by muse, mutect2
- ZNF91 | c.3096T>C p.N1032= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100322630; called by muse, mutect2, varscan2
- CCDC180 | c.-31T>G | 5'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100826666; called by muse, mutect2
- SMARCB1 | c.363-2242C>T | Intron (SNP) | VAF 11/67 reads (16%) | catalogued as CM991144, COSV54093065; called by muse, mutect2, varscan2
- TFF3 | c.-73G>C | 5'UTR (SNP) | VAF 26/120 reads (22%) | catalogued as COSV52294751; called by muse, mutect2, varscan2
